Somatic mutation profile of tumor specimen TCGA-13-0804-01A (aliquot TCGA-13-0804-01A-01W-0371-08) from TCGA case TCGA-13-0804, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.0 years (27,021 days).
Specimen TCGA-13-0804-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02667fee-ea06-4848-975e-8cf3183c53c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0804-10A (Blood Derived Normal), aliquot TCGA-13-0804-10A-01W-0372-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17b4a836-ad6d-43f1-a592-b221f9cb1a23

The open-access MAF lists 41 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Frame Shift Del 3, Frame Shift Ins 2, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 52/68 reads (76%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ADCY10 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 247/543 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV63241614; called by muse, mutect2, varscan2
- ADGRV1 | c.17825C>T p.T5942I | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1185880350; called by muse, mutect2
- AKAP8L | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV68473708; called by muse, mutect2, varscan2
- ATG3 | c.841G>T p.G281W | Missense Mutation (SNP) | VAF 108/377 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV51927264, COSV99344134; called by muse, mutect2, varscan2
- CBLC | c.1198del p.S400Vfs*55 | Frame Shift Del (DEL) | VAF 43/69 reads (62%) | catalogued as COSV54323387; called by mutect2, pindel, varscan2
- CCNT1 | c.1081del p.D361Ifs*29 | Frame Shift Del (DEL) | VAF 145/422 reads (34%) | catalogued as COSV56064695; called by mutect2, pindel, varscan2
- CEP350 | c.5233G>T p.G1745C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62604386; called by muse, mutect2, varscan2
- COPG1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs781314015, COSV59114656; called by muse, mutect2, varscan2
- FAM83A | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373188549; called by muse, mutect2, varscan2
- FNTB | c.1047dup p.L350Afs*4 | Frame Shift Ins (INS) | VAF 13/90 reads (14%) | catalogued as rs768774237; called by mutect2, varscan2
- GPR101 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV53237840; called by muse, mutect2, varscan2
- IGHD | c.285_287del p.E96del | In Frame Del (DEL) | VAF 41/96 reads (43%) | catalogued as rs750589341; called by mutect2, pindel, varscan2
- KLRC3 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV67250730; called by muse, mutect2, varscan2
- MCAM | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as COSV50641565; called by muse, mutect2, varscan2
- NALCN | c.4633C>T p.R1545W | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1407616507, COSV51930868; called by muse, mutect2, varscan2
- NGEF | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV50927990; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 44/273 reads (16%) | catalogued as rs754860965; called by mutect2, varscan2
- OR11H6 | c.527T>A p.V176D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59644452; called by muse, mutect2, varscan2
- PCDH19 | c.1013A>T p.D338V | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55265482; called by muse, mutect2, varscan2
- PCDHB2 | c.1835C>A p.T612K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99164798; called by muse, mutect2, varscan2
- PER3 | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs776696531, COSV62706380; called by muse, mutect2, varscan2
- PLEKHF1 | c.228C>G p.S76R | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV101460757; called by muse, mutect2
- PTPRZ1 | c.5093C>T p.A1698V | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66439327; called by muse, mutect2, varscan2
- SIK3 | c.3725G>A p.R1242H (on ENST00000445177 / NM_001366686.2; = p.R1200H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/189 reads (82%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs780688517, COSV99407689; called by muse, mutect2, varscan2
- SLCO1A2 | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs754967522, COSV56604657; called by muse, mutect2, varscan2
- TARS3 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60108457; called by muse, mutect2, varscan2
- TET1 | c.3769G>T p.V1257F | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs935570059, COSV65385770; called by muse, mutect2, varscan2
- TMEFF2 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99771336; called by muse, mutect2
- TRIP11 | c.5532del p.N1845Tfs*4 | Frame Shift Del (DEL) | VAF 56/170 reads (33%) | catalogued as COSV50928502, COSV99970425; called by mutect2, pindel*, varscan2
- ZBED6CL | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs374205555, COSV59604906; called by muse, mutect2, varscan2
- JAK1 | c.1838A>G p.E613G | Missense Mutation (SNP) | VAF 11/305 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- ARSI | c.510G>A p.S170= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as rs149029950; called by muse, varscan2
- C2orf16 | c.1764A>G p.V588= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as COSV62676464; called by muse, mutect2, varscan2
- CPS1 | c.282C>G p.L94= | Silent (SNP) | VAF 256/612 reads (42%) | catalogued as COSV51813714; called by muse, mutect2, varscan2
- CYP3A4 | c.873C>T p.S291= | Silent (SNP) | VAF 174/329 reads (53%) | catalogued as rs187260898, COSV60502644; called by muse, mutect2, varscan2
- DHX57 | c.1422A>T p.A474= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as rs1190074364, COSV54885920, COSV54886648; called by muse, mutect2, varscan2
- GPRASP1 | c.1971G>C p.G657= | Silent (SNP) | VAF 140/351 reads (40%) | catalogued as COSV64355871, COSV64355878; called by muse, mutect2, varscan2
- SYNJ1 | c.4029G>A p.P1343= | Silent (SNP) | VAF 121/293 reads (41%) | catalogued as rs372695378, COSV59146058; ClinVar: likely benign; called by muse, mutect2, varscan2
- XPNPEP1 | c.1798C>T p.L600= | Silent (SNP) | VAF 234/558 reads (42%) | catalogued as COSV59168822; called by muse, mutect2, varscan2
- CASR | c.1378-6254G>C | Intron (SNP) | VAF 143/509 reads (28%) | catalogued as COSV56138580; called by muse, mutect2, varscan2
